Somatic mutation profile of tumor specimen 0DWNTY from CCDI case PBCPKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 21.5 years (7,867 days).
Specimen 0DWNTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25cd827c-4841-458b-b71a-31f67661114a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3502c501-e5a3-46bc-a737-2bc0afa60083

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYBL1 | c.1405A>C p.N469H | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.235); called by muse, mutect2
- TMEM232 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.068); called by muse, mutect2
